Gene-level copy-number profile of tumor specimen ALCH-B1RP-TTP1-A from ALCHEMIST case ALCH-B1RP, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.6 years (23,595 days).
Specimen ALCH-B1RP-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5bda4672-4712-4fe9-8a21-c862cf3130e6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1RP-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/af603721-bca1-499a-92d0-bf15d450d34a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 85; copy number 1: 7,798; copy number 2: 50,102; copy number 3: 652; copy number 4: 198; copy number 5: 35; copy number 6: 29; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,978,926–17,011,928, 3 genes (within-gene range 0–1): AL049569.1, ATP13A2, AL049569.3.
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:177,476,631–177,497,606, 2 genes (within-gene range 0–1): AC145098.2, PDLIM7.
- chr5:180,684,766–180,686,546, 1 gene: LINC02222.
- chr7:152,445,477–152,465,549, 2 genes: CCT8L1P, LINC01003.
- chr9:136,830,957–136,831,023, 1 gene (within-gene range 0–2): MIR4292.
- chr10:86,654,547–86,666,848, 1 gene: OPN4.
- chr11:3,225,030–3,232,838, 2 genes: MRGPRE, AC109309.1.
- chr11:134,032,216–134,067,936, 2 genes: LINC02731, AP000911.1.
- chr14:100,826,284–100,829,454, 2 genes (within-gene range 0–2): AL117190.3, AL117190.7.
- chr14:102,582,888–102,583,177, 1 gene: RN7SL546P.
- chr15:25,172,635–25,250,940, 43 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:68,778,535–68,820,897, 2 genes (within-gene range 0–2): ANP32A, MIR4312.
- chr15:75,674,322–75,712,848, 3 genes (within-gene range 0–1): CSPG4, AC105020.4, AC105020.1.
- chr15:78,749,833–78,753,373, 2 genes: AC022748.3, AC022748.1.
- chr15:89,608,789–89,655,467, 1 gene (within-gene range 0–2): KIF7.
- chr16:3,581,181–3,583,266, 1 gene (within-gene range 0–1): AC006111.1.
- chr16:4,796,968–4,802,880, 1 gene: ROGDI.
- chr16:89,640,816–89,657,738, 1 gene: CHMP1A.
- chr16:89,818,179–89,871,319, 1 gene: SPIRE2.
- chr16:89,906,157–89,938,761, 5 genes (within-gene range 0–1): AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3.
- chr17:67,019,934–67,021,743, 1 gene (within-gene range 0–1): AC005544.1.
- chr22:19,146,993–19,178,739, 3 genes: GSC2, LINC01311, SLC25A1.
- chr22:24,181,487–24,189,106, 1 gene: SUSD2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 67 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:30,365,405–30,365,684, 1 gene, copy number 6: AC114300.1.
- chr7:37,032–37,477, 1 gene, copy number 6: AC215522.1.
- chr7:57,828,331–57,837,046, 2 genes, copy number 6: AC023141.7, AC023141.13.
- chr8:38,269,704–38,382,272, 1 gene, copy number 5 (within-gene range 2–5): NSD3.
- chr8:38,335,981–39,522,852, 26 genes, copy number 5: AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A.
- chr8:40,900,016–41,032,998, 2 genes, copy number 5: AC048387.1, RNU6-356P.
- chr9:136,759,634–136,766,255, 1 gene, copy number 5: LCN15.
- chr11:69,771,022–70,436,584, 23 genes, copy number 6: FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr14:75,633,625–75,955,079, 4 genes, copy number 5 (within-gene range 2–5): TTLL5, ERG28, AF107885.2, AF107885.1.
- chr22:18,846,811–18,861,049, 2 genes, copy number 6 (within-gene range 6–9): AC008132.1, BCRP7.
- chr22:18,906,028–18,947,741, 4 genes, copy number 5–12: DGCR6, AC007326.4, PRODH, AC007326.5.

Autosomal genes at a single copy (total copy number 1): 4,942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
